Gene-level copy-number profile of tumor specimen TCGA-09-2045-01A from TCGA case TCGA-09-2045, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 50.1 years (18,285 days).
Specimen TCGA-09-2045-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c7485ff7-5733-441c-8496-c28f0056e5b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-2045-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c35f1894-bd21-4b8e-ae80-ee4427ce7264

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,336; copy number 2: 39,572; copy number 3: 8,212; copy number 4: 1,661; copy number 5: 32; copy number 7: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-2045-01): tumor purity 0.92, ploidy 2.05, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 35 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,658,703–153,726,353, 7 genes, copy number 5: SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA.
- chr2:20,155,618–20,175,909, 3 genes, copy number 7: RPS16P2, RN7SL140P, RNU6-961P.
- chr7:132,648,794–133,170,514, 9 genes, copy number 5: FLJ40288, AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7.
- chr7:133,290,881–133,315,413, 2 genes, copy number 5: MIR6133, AC083875.1.
- chr10:44,712–744,958, 14 genes, copy number 5: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1.

Autosomal genes at a single copy (total copy number 1): 9,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
